Somatic mutation profile of tumor specimen TCGA-AB-2940-03A (aliquot TCGA-AB-2940-03A-01W-0733-08) from TCGA case TCGA-AB-2940, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.3 years (12,876 days).
Specimen TCGA-AB-2940-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ffff486-95a7-4e12-8da3-d5b3d33baedc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2940-11A (Solid Tissue Normal), aliquot TCGA-AB-2940-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f8f5ec3-f486-46e9-a1d6-4734469708e8

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.923_925dup p.V308dup | In Frame Ins (INS) | VAF 42/100 reads (42%) | hotspot (GDC flag); catalogued as COSV57195593, COSV57196047, COSV57197741; called by mutect2, varscan2
- IRF1 | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99810483; called by muse, mutect2
- DENND2D | c.273G>A p.E91= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as rs1481825433, COSV62958599; called by muse, mutect2, varscan2
